Somatic mutation profile of tumor specimen C3L-00413-01 (aliquot CPT0009980006) from CPTAC case C3L-00413, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.1 years (21,961 days).
Specimen C3L-00413-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df770979-e496-451d-82d7-caed96159201.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00413-31 (Blood Derived Normal), aliquot CPT0019850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b7df5f-ff09-4b8d-8fcf-46413c6df2c8

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 20, 3'UTR 4, Intron 3, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1, RNA 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 137/361 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.783_784del p.N262Qfs*35 | Frame Shift Del (DEL) | VAF 155/288 reads (54%) | catalogued as rs1554825249; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRA1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs1339448025; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 60/157 reads (38%) | catalogued as rs758608743; called by mutect2, varscan2
- CPS1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs150314086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSF | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.108); catalogued as rs765758974; called by muse, mutect2, varscan2
- DMXL1 | c.8041G>T p.V2681L | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs774524670, COSV60712023; called by muse, mutect2, varscan2
- EDA | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.006); catalogued as COSV52144812; called by muse, mutect2, varscan2
- ELOA3D | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 94/723 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1414333526; called by muse, mutect2, varscan2
- FAM166B | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs755029074; called by muse, mutect2, varscan2
- FAM83A | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149619029; called by muse, mutect2, varscan2
- FCGR2A | c.911A>G p.Y304C (on ENST00000271450 / NM_001136219.3; = p.Y303C on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1205397367; called by muse, mutect2, varscan2
- GLI3 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs552755211, COSV101229958; called by muse, mutect2, varscan2
- GRAMD1B | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 125/167 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1425676115; called by muse, mutect2, varscan2
- HJURP | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs777495361; called by muse, mutect2, varscan2
- LOXHD1 | c.5731G>A p.G1911R (on ENST00000642948; = p.G1849R on NM_144612.7) | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780560784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MANSC1 | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV67110714; called by muse, mutect2, varscan2
- MYO18B | c.4967C>T p.S1656L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs376592545; called by muse, mutect2, varscan2
- OGT | c.1051C>G p.R351G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV65482374; called by muse, mutect2, varscan2
- PCDHB1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs1004262128, COSV60629568; called by muse, mutect2, varscan2
- PDCD1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs979390849; called by muse, mutect2, varscan2
- PTPRU | c.4156C>T p.R1386C | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111220; called by muse, mutect2, varscan2
- RAD23B | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.661); catalogued as rs372514872; called by muse, mutect2, varscan2
- RBM20 | c.2149C>A p.Q717K | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.341); catalogued as rs551819918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX1 | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs543467989; called by muse, mutect2, varscan2
- SI | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747951287; called by muse, mutect2, varscan2
- SIPA1L3 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV55912629; called by muse, mutect2, varscan2
- SLC2A9 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs376668342; called by muse, varscan2
- SLITRK1 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100999885; called by muse, mutect2, varscan2
- STK10 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51574174, COSV51577312; called by muse, mutect2, varscan2
- TFAP2B | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV53825326; called by muse, mutect2, varscan2
- TTN | c.102423G>C p.Q34141H (on ENST00000591111; = p.Q26717H on NM_003319.4) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | PolyPhen probably damaging (0.997); catalogued as COSV60017817; called by muse, mutect2, varscan2
- VPS13D | c.8216G>A p.R2739H | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs762329183; called by muse, mutect2, varscan2
- AATK | c.2662C>T p.P888S (on ENST00000326724 / NM_001080395.3; = p.P785S on NM_004920.2) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY6 | c.2864A>T p.D955V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ADCY6 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CFL1 | c.53_78del p.M18Rfs*16 | Frame Shift Del (DEL) | VAF 80/246 reads (33%) | called by mutect2, pindel, varscan2
- CHRNA1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 282/530 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSF1R | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- GKAP1 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- INSL6 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, varscan2
- MROH7 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- OXR1 | c.1648A>C p.K550Q (on ENST00000442977 / NM_001198532.1; = p.K549Q on NM_018002.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDE1C | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 138/244 reads (57%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PSD3 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PSEN1 | c.548_548+2dup | In Frame Ins (INS) | VAF 54/161 reads (34%) | called by mutect2, pindel, varscan2
- TAPBPL | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TUBA3C | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UGT2B7 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- VNN1 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ZIC5 | c.1016C>A p.A339E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by mutect2, varscan2
- A4GALT | c.363C>T p.N121= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as rs1034139444, COSV99966798; called by muse, mutect2, varscan2
- AGRN | c.840C>T p.P280= | Silent (SNP) | VAF 70/156 reads (45%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.114C>T p.A38= | Silent (SNP) | VAF 120/291 reads (41%) | catalogued as COSV99357937; called by muse, mutect2, varscan2
- CBX2 | c.615C>T p.S205= | Silent (SNP) | VAF 59/165 reads (36%) | catalogued as rs374351738; called by muse, mutect2, varscan2
- CCDC168 | c.7311G>A p.V2437= | Silent (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- EDRF1 | c.2949G>A p.P983= (on ENST00000356792 / NM_001202438.2; = p.P949= on NM_015608.2) | Silent (SNP) | VAF 60/523 reads (11%) | catalogued as rs774576418, COSV61763411; called by muse, mutect2, varscan2
- FRMD3 | c.489C>T p.Y163= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs746917345, COSV58460392; called by muse, mutect2, varscan2
- KCNH4 | c.1401C>T p.H467= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as rs139967980; called by muse, mutect2, varscan2
- MADD | c.3783A>G p.P1261= | Silent (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- MLLT3 | c.510C>T p.S170= | Silent (SNP) | VAF 89/521 reads (17%) | catalogued as rs553184543, COSV63497932; called by muse, varscan2
- OR2W3 | c.723C>T p.C241= | Silent (SNP) | VAF 103/254 reads (41%) | catalogued as rs200968890, COSV100831799; called by muse, mutect2, varscan2
- PRSS35 | c.987C>T p.D329= | Silent (SNP) | VAF 101/267 reads (38%) | catalogued as rs568367796, COSV63801066; called by muse, mutect2, varscan2
- SCAF1 | c.1836C>T p.S612= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs1334373922; called by muse, mutect2, varscan2
- SCRT2 | c.402C>T p.D134= | Silent (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SI | c.3075C>T p.H1025= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs897900776; called by muse, mutect2, varscan2
- SLC26A3 | c.531G>A p.A177= | Silent (SNP) | VAF 114/412 reads (28%) | catalogued as rs543522300, COSV100384820, COSV60639071; called by muse, mutect2, varscan2
- TAL1 | c.903G>A p.P301= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs776394227, COSV53745002; called by muse, mutect2, varscan2
- TMEM126A | c.108G>A p.S36= | Silent (SNP) | VAF 102/292 reads (35%) | catalogued as rs767966668, COSV58735123; called by muse, mutect2, varscan2
- TPRN | c.1827G>A p.E609= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as rs376313860, COSV100119284; called by muse, mutect2, varscan2
- ZNF143 | c.1437C>T p.D479= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs200523570; called by muse, mutect2, varscan2
- ALDH6A1 | c.-2C>T | 5'UTR (SNP) | VAF 141/365 reads (39%) | catalogued as rs758880945; called by muse, mutect2, varscan2
- CRACR2A | c.*23C>T | 3'UTR (SNP) | VAF 57/187 reads (30%) | called by muse, mutect2, varscan2
- DTWD2 | c.218+127A>G | Intron (SNP) | VAF 80/197 reads (41%) | catalogued as rs1194307697; called by muse, mutect2, varscan2
- GDI1 | c.587+36C>T | Intron (SNP) | VAF 51/137 reads (37%) | catalogued as rs370057720; called by muse, mutect2, varscan2
- IRAK1 | c.136+34C>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- JAKMIP3 | c.*222C>T | 3'UTR (SNP) | VAF 28/178 reads (16%) | catalogued as rs1268763779; called by muse, mutect2, varscan2
- KRT86 | c.*30C>T | 3'UTR (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- LINC01159 | n.158C>T | RNA (SNP) | VAF 92/301 reads (31%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1470145 C>T | 3'Flank (SNP) | VAF 100/247 reads (40%) | catalogued as rs777203137; called by muse, mutect2, varscan2
- SNX20 | chr16:50668026 C>T | 3'Flank (SNP) | VAF 91/254 reads (36%) | catalogued as rs985229274; called by muse, mutect2, varscan2
- XIAP | c.*527A>G | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
